Gene-level copy-number profile of tumor specimen TCGA-G5-6572-02A from TCGA case TCGA-G5-6572, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; Age at diagnosis: 56.1 years (20,475 days).
Specimen TCGA-G5-6572-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.134b4f8d-6920-4201-898d-800bb2f9ef70.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G5-6572-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 364 have no estimate.
https://portal.gdc.cancer.gov/files/1ec0e18e-ddba-4b59-b84b-4f6cd0fd834e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,391; copy number 1: 6,445; copy number 2: 33,015; copy number 3: 14,169; copy number 4: 2,186; copy number 5: 1,469; copy number 6: 485; copy number 12: 98; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:98,064,472–98,065,396, 1 gene: OR5AC1.
- chr17:18,450,244–18,551,705, 9 genes (within-gene range 0–2): KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,532 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene, copy number 15: CFHR3.
- chr3:143,503,275–143,518,229, 2 genes, copy number 5: GAPDHP47, ST13P15.
- chr13:53,099,397–55,174,548, 19 genes, copy number 5 (within-gene range 4–5): LINC01065, AL136359.1, PCDH8P1, AL356295.1, RN7SL618P, AL450423.2, AL450423.1, ZNF646P1, LINC00558, LINC00458, AL356052.1, MIR1297, RPL13AP25, AL442636.1, AL512655.1, AL390964.1, LINC02335, AL139038.1, MIR5007.
- chr13:63,034,668–114,337,626, 606 genes, copy number 5–6 (broad region; genes not listed).
- chr14:105,764,503–106,344,833, 98 genes, copy number 12 (broad region; genes not listed).
- chr20:25,611,153–61,940,617, 806 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,445. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
